Somatic mutation profile of cancer-model specimen HCM-BROD-0477-C16-85M (3D Organoid, passage 5; aliquot HCM-BROD-0477-C16-85M-01D-A83U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0477-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 68.6 years (25,046 days).
Specimen HCM-BROD-0477-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79fb2919-0817-451d-aea2-90de0b3170e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0477-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0477-C16-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f85623af-7733-4868-8cc6-43389125e908

The open-access MAF lists 140 somatic variants for this specimen: 116 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Frame Shift Ins 23, Frame Shift Del 22, Silent 20, In Frame Del 11, In Frame Ins 7, Splice Site 5, Nonsense Mutation 3, Intron 3, 5'UTR 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHM | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 44/247 reads (18%) | catalogued as rs786205604, COSV63305405; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPEB3 | c.1165+1G>T p.X389_splice | Splice Site (SNP) | VAF 49/175 reads (28%) | catalogued as rs1391087552; called by muse, mutect2, varscan2
- ELAVL4 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 215/512 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs763451875; called by muse, mutect2, varscan2
- GRAMD1B | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 120/761 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs1393560591; called by muse, mutect2, varscan2
- ITGAL | c.497G>A p.S166N | Missense Mutation (SNP) | VAF 62/710 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100776339; called by muse, mutect2
- LACC1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 114/261 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.828); catalogued as rs761293228; called by muse, mutect2, varscan2
- LAMA1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 69/719 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs778434634, COSV67531138; called by muse, mutect2, varscan2
- MROH5 | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 62/407 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.06); catalogued as rs762008642; called by mutect2, varscan2
- NPPB | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 55/540 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs777621972, COSV64687232; called by muse, mutect2, varscan2
- OR2A2 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 18/417 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs373747609; called by muse, mutect2
- SYT3 | c.1281G>A p.S427= | Splice Region (SNP) | VAF 579/999 reads (58%) | catalogued as rs778913847, COSV58896509; called by muse, mutect2, varscan2
- TMEM87A | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs374342321; called by muse, mutect2, varscan2
- TOP2A | c.2229G>T p.K743N | Missense Mutation (SNP) | VAF 48/384 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV70732591; called by muse, mutect2, varscan2
- TP53 | c.714_715insTG p.N239* | Frame Shift Ins (INS) | VAF 237/321 reads (74%) | catalogued as COSV52663173, COSV52791488; called by mutect2, pindel, varscan2
- ZFHX4 | c.4039G>A p.E1347K | Missense Mutation (SNP) | VAF 78/576 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV50683097; called by muse, mutect2, varscan2
- ZNF107 | c.2048A>T p.K683M | Missense Mutation (SNP) | VAF 145/269 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61331563; called by muse, mutect2, varscan2
- ZNF148 | c.2235del p.T746Lfs*10 | Frame Shift Del (DEL) | VAF 220/563 reads (39%) | catalogued as COSV62302097; called by mutect2, pindel, varscan2
- ZNF780B | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 77/403 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55461943; called by muse, mutect2, varscan2
- ACTL10 | c.168_200del p.R57_L67del | In Frame Del (DEL) | VAF 286/1023 reads (28%) | called by mutect2, pindel, varscan2
- ADGRG3 | c.1285_1288dup p.A430Vfs*138 | Frame Shift Ins (INS) | VAF 47/257 reads (18%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.13707_13708del p.N4569Kfs*31 | Frame Shift Del (DEL) | VAF 122/383 reads (32%) | called by mutect2, pindel, varscan2
- ADRB3 | c.285del p.T96Pfs*4 | Frame Shift Del (DEL) | VAF 99/861 reads (11%) | called by mutect2, pindel, varscan2
- AGBL2 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 70/772 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- AGTPBP1 | c.2921G>T p.S974I (on ENST00000357081 / NM_001330701.2; = p.S934I on NM_015239.2) | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGTPBP1 | c.2920A>T p.S974C (on ENST00000357081 / NM_001330701.2; = p.S934C on NM_015239.2) | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID1A | c.2227dup p.Q743Pfs*74 | Frame Shift Ins (INS) | VAF 366/884 reads (41%) | called by mutect2, pindel, varscan2
- ASZ1 | c.106-6_130del p.X36_splice | Splice Site (DEL) | VAF 51/61 reads (84%) | called by mutect2, pindel, varscan2
- B4GALNT3 | c.166_169dup p.R57Tfs*41 | Frame Shift Ins (INS) | VAF 68/422 reads (16%) | called by mutect2, pindel, varscan2
- BLMH | c.99_100del p.H34Rfs*59 | Frame Shift Del (DEL) | VAF 357/599 reads (60%) | called by mutect2, pindel, varscan2
- CALN1 | c.576C>A p.S192R (on ENST00000329008 / NM_001017440.3; = p.S234R on NM_031468.4) | Missense Mutation (SNP) | VAF 73/497 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CASP10 | c.123_125del p.L42del | In Frame Del (DEL) | VAF 187/416 reads (45%) | called by mutect2, pindel, varscan2
- CCR5 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 66/365 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CD5L | c.1018del p.D340Mfs*29 | Frame Shift Del (DEL) | VAF 53/477 reads (11%) | called by mutect2, pindel*, varscan2
- CFAP57 | c.90_91insG p.I31Dfs*46 | Frame Shift Ins (INS) | VAF 203/486 reads (42%) | called by mutect2, pindel, varscan2
- CFHR5 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CLIC1 | c.115_130del p.V39Pfs*56 | Frame Shift Del (DEL) | VAF 182/654 reads (28%) | called by mutect2, pindel, varscan2
- CNKSR2 | c.871T>G p.L291V | Missense Mutation (SNP) | VAF 74/480 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- COLEC11 | c.127_130+19del p.X43_splice | Splice Site (DEL) | VAF 50/404 reads (12%) | called by mutect2, pindel
- CTNND1 | c.867G>T p.M289I | Missense Mutation (SNP) | VAF 348/726 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP26B1 | c.1245T>G p.D415E | Missense Mutation (SNP) | VAF 114/1352 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.014); called by muse, mutect2
- CYP2B6 | c.222dup p.V75Rfs*19 | Frame Shift Ins (INS) | VAF 340/513 reads (66%) | called by mutect2, pindel, varscan2
- DCBLD1 | c.292_293insGTC p.Y98delinsCH | In Frame Ins (INS) | VAF 112/247 reads (45%) | called by mutect2, pindel, varscan2
- DCN | c.852_855dup p.G286Tfs*8 | Frame Shift Ins (INS) | VAF 59/251 reads (24%) | called by mutect2, pindel, varscan2
- DKK1 | c.218dup p.Y74Vfs*5 | Frame Shift Ins (INS) | VAF 177/961 reads (18%) | called by mutect2, pindel, varscan2
- DNASE1L2 | c.596_599del p.M199Sfs*23 | Frame Shift Del (DEL) | VAF 296/503 reads (59%) | called by mutect2, pindel, varscan2
- DYRK1A | c.159_160del p.S54Cfs*6 | Frame Shift Del (DEL) | VAF 235/497 reads (47%) | called by mutect2, pindel, varscan2
- E2F8 | c.2098del p.L700* | Frame Shift Del (DEL) | VAF 313/622 reads (50%) | called by mutect2, pindel, varscan2
- ELAPOR2 | c.379_381delinsGG p.T127Gfs*53 | Frame Shift Del (DEL) | VAF 150/972 reads (15%) | called by pindel, varscan2*
- EPB41L2 | c.2435_2440del p.T812_V813del | In Frame Del (DEL) | VAF 64/548 reads (12%) | called by mutect2, pindel, varscan2
- ERI1 | c.914del p.I305Kfs*23 | Frame Shift Del (DEL) | VAF 227/317 reads (72%) | called by mutect2, pindel, varscan2
- ESYT1 | c.1513_1514del p.L505Vfs*43 | Frame Shift Del (DEL) | VAF 233/336 reads (69%) | called by mutect2, pindel*, varscan2*
- FAM83G | c.612_613dup p.I205Tfs*81 | Frame Shift Ins (INS) | VAF 314/593 reads (53%) | called by pindel, varscan2
- FAT4 | c.11707A>G p.I3903V | Missense Mutation (SNP) | VAF 165/380 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXW10 | c.1782_1797del p.L595Afs*10 | Frame Shift Del (DEL) | VAF 124/132 reads (94%) | called by mutect2, pindel, varscan2
- FLG | c.8952_8956del p.Q2984Hfs*29 | Frame Shift Del (DEL) | VAF 126/812 reads (16%) | called by mutect2, pindel, varscan2
- FLG | c.2342A>T p.D781V | Missense Mutation (SNP) | VAF 45/765 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2
- GABBR2 | c.2154_2168del p.Q720_V724del | In Frame Del (DEL) | VAF 66/710 reads (9%) | called by mutect2, pindel
- GPRIN1 | c.1859_1873del p.T620_P624del | In Frame Del (DEL) | VAF 77/478 reads (16%) | called by mutect2, pindel, varscan2
- HAUS3 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HSP90AB1 | c.1487del p.N496Tfs*18 | Frame Shift Del (DEL) | VAF 311/788 reads (39%) | called by mutect2, pindel, varscan2
- INHBA | c.951G>T p.K317N | Missense Mutation (SNP) | VAF 97/656 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.908); called by muse, varscan2
- JSRP1 | c.597dup p.K200Qfs*58 | Frame Shift Ins (INS) | VAF 425/745 reads (57%) | called by mutect2, pindel, varscan2
- KCNN3 | c.664T>A p.S222T | Missense Mutation (SNP) | VAF 72/1476 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); called by muse, mutect2
- LCK | c.697T>A p.W233R | Missense Mutation (SNP) | VAF 96/983 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LTBP2 | c.1927A>T p.S643C | Missense Mutation (SNP) | VAF 318/714 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- LTN1 | c.4893_4894insGTA p.T1631_T1632insV | In Frame Ins (INS) | VAF 69/186 reads (37%) | called by mutect2, pindel, varscan2
- LYPLA2 | c.515_530del p.H172Pfs*10 | Frame Shift Del (DEL) | VAF 324/843 reads (38%) | called by mutect2, pindel, varscan2
- MACF1 | c.3199dup p.V1067Gfs*12 | Frame Shift Ins (INS) | VAF 88/692 reads (13%) | called by mutect2, pindel, varscan2
- METTL17 | c.296dup p.L99Ffs*13 | Frame Shift Ins (INS) | VAF 315/649 reads (49%) | called by mutect2, pindel, varscan2
- MON2 | c.5020_5027del p.A1674Pfs*19 | Frame Shift Del (DEL) | VAF 101/320 reads (32%) | called by mutect2, pindel, varscan2
- MS4A14 | c.813_830del p.F271_E277delinsL | In Frame Del (DEL) | VAF 79/806 reads (10%) | called by mutect2, pindel
- MVB12A | c.97T>A p.C33S | Missense Mutation (SNP) | VAF 258/349 reads (74%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO16 | c.4141G>A p.G1381R | Missense Mutation (SNP) | VAF 131/873 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NAMPT | c.1289_1290insTC p.L430Ffs*39 | Frame Shift Ins (INS) | VAF 282/643 reads (44%) | called by mutect2, pindel, varscan2
- NBEAL1 | c.6087del p.Y2029* | Frame Shift Del (DEL) | VAF 64/218 reads (29%) | called by mutect2, pindel, varscan2
- NDUFB10 | c.114_115insACGC p.V39Tfs*33 | Frame Shift Ins (INS) | VAF 130/507 reads (26%) | called by mutect2, pindel, varscan2
- NFKBIA | c.134_135insTCT p.M45delinsIL | In Frame Ins (INS) | VAF 490/791 reads (62%) | called by mutect2, pindel, varscan2
- NNT | c.2606_2621delinsTCAT p.G869_Y874delinsVI | In Frame Del (DEL) | VAF 111/360 reads (31%) | called by pindel, varscan2*
- NRG2 | c.2464_2465insGTA p.Y822delinsCN | In Frame Ins (INS) | VAF 411/748 reads (55%) | called by mutect2, pindel, varscan2
- OR11G2 | c.736T>A p.F246I | Missense Mutation (SNP) | VAF 80/588 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR2A1 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 81/465 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OTOG | c.266dup p.D90Rfs*38 | Frame Shift Ins (INS) | VAF 55/335 reads (16%) | called by mutect2, pindel, varscan2
- PCNX1 | c.108_109dup p.Y37Sfs*22 | Frame Shift Ins (INS) | VAF 485/1254 reads (39%) | called by mutect2, pindel, varscan2
- PDIA4 | c.1693G>T p.V565L (on ENST00000286091 / NM_001371244.1; = p.V564L on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 236/592 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2
- PIK3R1 | c.101_102dup p.G35Kfs*4 | Frame Shift Ins (INS) | VAF 66/497 reads (13%) | called by mutect2, pindel, varscan2
- PKLR | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 204/2314 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2
- PLEKHA3 | c.312dup p.E105Rfs*4 | Frame Shift Ins (INS) | VAF 26/196 reads (13%) | called by pindel, varscan2
- PLEKHA3 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 28/168 reads (17%) | called by muse, varscan2
- POC5 | c.299A>G p.K100R (on ENST00000428202 / NM_001099271.2; = p.K75R on NM_152408.2) | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- POFUT1 | c.1023_1024dup p.Y342Cfs*22 | Frame Shift Ins (INS) | VAF 77/640 reads (12%) | called by mutect2, pindel, varscan2
- PPIL4 | c.660_662del p.Q220_A221delinsH | In Frame Del (DEL) | VAF 27/198 reads (14%) | called by mutect2, pindel, varscan2
- PPP2CB | c.34_35insCAC p.D11_Q12insP | In Frame Ins (INS) | VAF 338/799 reads (42%) | called by mutect2, pindel, varscan2
- RAPH1 | c.1489dup p.V497Gfs*29 (on ENST00000319170 / NM_213589.3; = p.V549Gfs*29 on NM_203365.4) | Frame Shift Ins (INS) | VAF 171/326 reads (52%) | called by mutect2, pindel, varscan2
- REV3L | c.1655A>C p.K552T | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RHOB | c.160_162del p.E54del | In Frame Del (DEL) | VAF 504/513 reads (98%) | called by mutect2, pindel, varscan2
- ROS1 | c.2564_2573del p.I855Tfs*31 | Frame Shift Del (DEL) | VAF 24/163 reads (15%) | called by mutect2, pindel, varscan2
- SAMD4A | c.722C>G p.S241* | Nonsense Mutation (SNP) | VAF 68/413 reads (16%) | called by muse, mutect2, varscan2
- SCN1A | c.2176+1G>T p.X726_splice (on ENST00000303395 / NM_001202435.3; = p.X715_splice on NM_006920.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 108/108 reads (100%) | called by muse, mutect2, varscan2
- SDE2 | c.1289_1299del p.R430Kfs*5 | Frame Shift Del (DEL) | VAF 121/482 reads (25%) | called by mutect2, pindel, varscan2
- SETX | c.5650_5652del p.V1884del | In Frame Del (DEL) | VAF 57/453 reads (13%) | called by mutect2, pindel, varscan2
- SLC28A2 | c.27dup p.I10Hfs*25 | Frame Shift Ins (INS) | VAF 82/426 reads (19%) | called by mutect2, varscan2
- SMAD6 | c.919_922del p.N307Pfs*231 | Frame Shift Del (DEL) | VAF 117/421 reads (28%) | called by mutect2, pindel, varscan2
- SSNA1 | c.53_72del p.X18_splice | Splice Site (DEL) | VAF 200/504 reads (40%) | called by mutect2, pindel, varscan2
- TBX2 | c.809A>T p.K270M | Missense Mutation (SNP) | VAF 57/255 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCEAL5 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 125/692 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCF20 | c.2409dup p.L804Sfs*27 | Frame Shift Ins (INS) | VAF 290/894 reads (32%) | called by mutect2, pindel, varscan2
- TMDD1 | c.707dup p.V237Gfs*39 | Frame Shift Ins (INS) | VAF 124/623 reads (20%) | called by mutect2, pindel, varscan2
- TMEM272 | c.-1_2dup p.D1_?0 | Translation Start Site (INS) | VAF 80/628 reads (13%) | called by mutect2, pindel, varscan2
- TRIAP1 | c.46_51del p.D16_Q17del | In Frame Del (DEL) | VAF 50/350 reads (14%) | called by mutect2, pindel, varscan2
- TTC30A | c.1465C>A p.H489N | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC30B | c.1465C>A p.H489N | Missense Mutation (SNP) | VAF 48/464 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, varscan2
- TTN | c.31927C>A p.P10643T (on ENST00000591111; = p.P9716T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WAC | c.724_726dup p.S243dup | In Frame Ins (INS) | VAF 126/461 reads (27%) | called by mutect2, pindel, varscan2
- WASF2 | c.221_223dup p.R74dup | In Frame Ins (INS) | VAF 152/450 reads (34%) | called by mutect2, pindel, varscan2
- WDFY4 | c.8546G>A p.S2849N | Missense Mutation (SNP) | VAF 86/950 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- ZCCHC2 | c.384del p.F129Sfs*152 | Frame Shift Del (DEL) | VAF 123/1302 reads (9%) | called by mutect2, pindel, varscan2
- ANKS1A | c.2502C>T p.Y834= | Silent (SNP) | VAF 309/695 reads (44%) | catalogued as rs138086834, COSV64459859; called by muse, mutect2
- CCDC85B | c.18C>A p.G6= | Silent (SNP) | VAF 89/828 reads (11%) | catalogued as rs944804464; called by muse, mutect2, varscan2
- CCPG1 | c.732A>G p.Q244= | Silent (SNP) | VAF 85/85 reads (100%) | catalogued as rs776883716; called by muse, mutect2, varscan2
- CELF6 | c.753G>T p.L251= | Silent (SNP) | VAF 22/791 reads (3%) | called by muse, mutect2
- CHL1 | c.1902T>C p.A634= (on ENST00000397491 / NM_001253387.1; = p.A650= on NM_006614.4) | Silent (SNP) | VAF 190/346 reads (55%) | called by muse, mutect2, varscan2
- CHSY1 | c.582C>A p.L194= | Silent (SNP) | VAF 94/705 reads (13%) | called by muse, mutect2, varscan2
- CKAP5 | c.4938C>T p.L1646= (on ENST00000529230 / NM_001008938.4; = p.L1586= on NM_014756.3) | Silent (SNP) | VAF 345/634 reads (54%) | catalogued as COSV100370686; called by muse, mutect2, varscan2
- DNAH10 | c.12177G>A p.R4059= (on ENST00000409039; = p.R3998= on NM_207437.3) | Silent (SNP) | VAF 24/470 reads (5%) | called by muse, mutect2
- MACROH2A2 | c.205A>C p.R69= | Silent (SNP) | VAF 350/650 reads (54%) | called by muse, mutect2
- MYLK | c.2850G>A p.Q950= | Silent (SNP) | VAF 417/860 reads (48%) | called by muse, mutect2, varscan2
- NOBOX | c.315C>T p.P105= | Silent (SNP) | VAF 95/384 reads (25%) | called by muse, mutect2, varscan2
- NUMB | c.219A>G p.K73= | Silent (SNP) | VAF 27/480 reads (6%) | called by muse, mutect2
- OR51L1 | c.465G>A p.L155= | Silent (SNP) | VAF 41/421 reads (10%) | called by muse, mutect2, varscan2
- PTCHD3 | c.1275A>G p.A425= | Silent (SNP) | VAF 203/559 reads (36%) | called by muse, mutect2, varscan2
- SLC8A2 | c.2061G>T p.G687= | Silent (SNP) | VAF 72/913 reads (8%) | called by muse, mutect2
- SPAG17 | c.6276T>C p.H2092= | Silent (SNP) | VAF 296/610 reads (49%) | catalogued as rs1244737062; called by muse, mutect2, varscan2
- SPATA48 | c.189T>G p.A63= | Silent (SNP) | VAF 71/569 reads (12%) | catalogued as COSV99248993; called by muse, mutect2, varscan2
- UPF3B | c.1323T>G p.L441= (on ENST00000276201 / NM_080632.3; = p.L428= on NM_023010.3) | Silent (SNP) | VAF 61/312 reads (20%) | called by muse, mutect2, varscan2
- WDFY4 | c.8547C>T p.S2849= | Silent (SNP) | VAF 86/946 reads (9%) | catalogued as rs993401916; called by muse, mutect2
- ZNF180 | c.1644G>A p.P548= | Silent (SNP) | VAF 96/1401 reads (7%) | catalogued as rs781643414, COSV55424646; called by muse, mutect2
- ELF2 | c.239-10582_239-10569del | Intron (DEL) | VAF 52/578 reads (9%) | called by mutect2, pindel
- MSH5 | c.1_5dup | 5'UTR (INS) | VAF 405/753 reads (54%) | called by mutect2, pindel, varscan2
- PRKAG2 | c.466+45210C>A | Intron (SNP) | VAF 102/561 reads (18%) | called by muse, mutect2, varscan2
- SORBS2 | c.-46+1319_-46+1328del | Intron (DEL) | VAF 258/460 reads (56%) | called by mutect2, pindel, varscan2
